Somatic mutation profile of tumor specimen C3L-02842-01 (aliquot CPT0172070006) from CPTAC case C3L-02842, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G4; Age at diagnosis: 68.2 years (24,927 days).
Specimen C3L-02842-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f46d5efc-e790-475a-ba94-dc81d3836220.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02842-31 (Blood Derived Normal), aliquot CPT0167410002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3006d5f2-d7f9-4ca9-bc0b-9ae74368cd3f

The open-access MAF lists 107 somatic variants for this specimen: 76 protein-altering or splice-affecting, 17 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 17, Intron 8, Frame Shift Del 7, Frame Shift Ins 4, Splice Site 3, 3'UTR 2, RNA 2, Splice Region 2, Nonsense Mutation 2, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 58/164 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs5030811, CD141839, CM961423, CM982005, COSV56545369, COSV56546151, COSV56556158, COSV56571206; called by muse, mutect2, varscan2
- ANKRD11 | c.2786del p.S929Mfs*48 | Frame Shift Del (DEL) | VAF 86/465 reads (18%) | catalogued as COSV56371342; called by mutect2, pindel, varscan2
- INTS6L | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.174); catalogued as COSV66086100; called by muse, mutect2, varscan2
- KRT9 | c.176G>C p.R59P | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.077); catalogued as rs778678852; called by muse, mutect2, varscan2
- MUC17 | c.9131G>T p.G3044V | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.972); catalogued as COSV60297764; called by muse, mutect2, varscan2
- NOTCH4 | c.541C>G p.H181D | Missense Mutation (SNP) | VAF 50/218 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1428690048; called by muse, mutect2, varscan2
- PBRM1 | c.2965+1del p.X989_splice | Splice Site (DEL) | VAF 12/80 reads (15%) | catalogued as COSV56271955, COSV56286695; called by mutect2, pindel, varscan2
- RECQL4 | c.1501G>A p.V501M | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1016151338; called by muse, mutect2, varscan2
- SON | c.3064C>T p.R1022W | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1488614940; called by muse, mutect2, varscan2
- ST18 | c.1382G>A p.C461Y | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.372); catalogued as rs772930467; called by muse, mutect2, varscan2
- TSPEAR | c.1943G>C p.G648A | Missense Mutation (SNP) | VAF 54/233 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV59955136; called by muse, mutect2, varscan2
- WNK4 | c.1260-2A>G p.X420_splice | Splice Site (SNP) | VAF 109/517 reads (21%) | catalogued as rs977677844; called by muse, mutect2, varscan2
- AASDH | c.2848T>C p.Y950H | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ACBD5 | c.533T>G p.L178R (on ENST00000375888 / NM_001352568.1; = p.L169R on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/239 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- AHCTF1 | c.736C>A p.L246M (on ENST00000366508; = p.L220M on NM_015446.5) | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AK9 | c.2704A>T p.T902S | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AKAP9 | c.5697G>A p.Q1899= (on ENST00000359028; = p.Q1867= on NM_005751.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 28/111 reads (25%) | called by muse, mutect2, varscan2
- AP1S3 | c.62T>G p.I21S | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.8); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ARHGEF28 | c.3671A>G p.N1224S | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP6V1H | c.1076_1077dup p.K360Lfs*23 | Frame Shift Ins (INS) | VAF 18/89 reads (20%) | called by mutect2, pindel, varscan2
- C2orf16 | c.5115del p.S1706Lfs*186 | Frame Shift Del (DEL) | VAF 80/493 reads (16%) | called by mutect2, pindel, varscan2
- CACNA1B | c.3326A>T p.K1109M | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- CAPRIN2 | c.1471C>T p.Q491* | Nonsense Mutation (SNP) | VAF 85/331 reads (26%) | called by muse, mutect2, varscan2
- CBLN1 | c.430G>T p.G144C | Missense Mutation (SNP) | VAF 63/321 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH22 | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDK5RAP2 | c.4244C>T p.T1415I | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CIR1 | c.699G>C p.K233N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); called by muse, varscan2
- COL12A1 | c.776T>A p.I259N | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL6A2 | c.2921T>G p.L974R | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- CUX2 | c.208A>T p.S70C | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CYP4A11 | c.998T>C p.I333T | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- DCTN1 | c.3349G>C p.A1117P | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- DDR1 | c.2380G>C p.G794R (on ENST00000324771; = p.G757R on NM_001954.4) | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPYSL3 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.298); called by muse, mutect2
- ENTPD1 | c.1195del p.T399Hfs*6 | Frame Shift Del (DEL) | VAF 39/188 reads (21%) | called by mutect2, pindel, varscan2
- FAT4 | c.14024C>G p.T4675S | Missense Mutation (SNP) | VAF 49/225 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- FER | c.1766del p.A589Vfs*13 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | called by mutect2, pindel, varscan2
- FFAR2 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- G6PC | c.180dup p.L61Tfs*16 | Frame Shift Ins (INS) | VAF 83/413 reads (20%) | called by mutect2, pindel, varscan2
- HSD3B7 | c.128A>C p.D43A | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HTR2A | c.1408T>A p.C470S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, varscan2
- ICAM3 | c.344-2_344-1del p.X115_splice | Splice Site (DEL) | VAF 22/86 reads (26%) | called by mutect2, pindel
- IGHG3 | c.356C>A p.S119Y | Missense Mutation (SNP) | VAF 52/297 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.364); called by muse, varscan2
- INPP5F | c.1448A>T p.K483I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ITGA2 | c.944T>C p.L315S | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- KISS1R | c.419G>C p.R140P | Missense Mutation (SNP) | VAF 104/434 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- KRTAP10-4 | c.801G>C p.Q267H | Missense Mutation (SNP) | VAF 127/532 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- LONP1 | c.2867C>T p.A956V | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); called by muse, mutect2
- MARS1 | c.1487C>T p.T496I | Missense Mutation (SNP) | VAF 55/274 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- METTL8 | c.466dup p.Y156Lfs*2 | Frame Shift Ins (INS) | VAF 9/38 reads (24%) | called by mutect2, pindel, varscan2
- MIER2 | c.583A>C p.K195Q | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR5B2 | c.11_34del p.C4_L12delinsF | In Frame Del (DEL) | VAF 16/56 reads (29%) | called by mutect2, pindel, varscan2
- PARP8 | c.2078C>G p.T693S | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- PHF8 | c.2221G>A p.D741N (on ENST00000357988 / NM_001184896.1; = p.D705N on NM_015107.3) | Missense Mutation (SNP) | VAF 71/371 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- PPP3CA | c.282A>C p.Q94H | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRPS2 | c.623T>C p.V208A | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRPSAP1 | c.1010_1017del p.T337Sfs*4 | Frame Shift Del (DEL) | VAF 19/75 reads (25%) | called by mutect2, pindel, varscan2
- RAB26 | c.121C>G p.P41A | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- RANBP3 | c.286T>C p.S96P | Missense Mutation (SNP) | VAF 47/233 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RANBP3 | c.285G>A p.R95= | Splice Region (SNP) | VAF 46/231 reads (20%) | called by muse, mutect2, varscan2
- SLC4A4 | c.1619T>A p.F540Y (on ENST00000264485 / NM_001098484.3; = p.F496Y on NM_003759.4) | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.162); called by muse, mutect2
- SYNE1 | c.8771_8783del p.Q2924Pfs*49 (on ENST00000367255 / NM_182961.4; = p.Q2931Pfs*49 on NM_033071.3) | Frame Shift Del (DEL) | VAF 60/261 reads (23%) | called by mutect2, pindel, varscan2
- TCF4 | c.1459C>G p.L487V | Missense Mutation (SNP) | VAF 33/258 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TCHH | c.1603G>C p.E535Q | Missense Mutation (SNP) | VAF 66/259 reads (25%) | PolyPhen benign (0.093); called by muse, mutect2, varscan2
- TLR6 | c.866T>A p.I289N | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TOP2A | c.1552T>G p.Y518D | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- TSC1 | c.1034C>T p.T345I | Missense Mutation (SNP) | VAF 42/228 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TTC14 | c.1816del p.T606Pfs*46 | Frame Shift Del (DEL) | VAF 37/166 reads (22%) | called by mutect2, pindel, varscan2
- TUSC3 | c.479C>G p.P160R | Missense Mutation (SNP) | VAF 45/242 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- UBE2D3 | c.243T>G p.N81K | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- VPS26A | c.756A>T p.L252F | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- WASHC2C | c.2262A>T p.K754N | Missense Mutation (SNP) | VAF 71/322 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- WNK2 | c.400G>T p.E134* | Nonsense Mutation (SNP) | VAF 21/86 reads (24%) | called by muse, mutect2, varscan2
- YARS1 | c.802dup p.L268Pfs*5 | Frame Shift Ins (INS) | VAF 18/117 reads (15%) | called by mutect2, pindel, varscan2
- YTHDF3 | c.127A>G p.T43A | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ZNF19 | c.223C>G p.L75V | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- ANXA1 | c.543T>G p.L181= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs1190074444; called by muse, mutect2, varscan2
- ARMC9 | c.1261A>C p.R421= | Silent (SNP) | VAF 20/117 reads (17%) | called by muse, mutect2, varscan2
- CARS2 | c.948A>G p.E316= | Silent (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- CCDC71 | c.1371G>A p.R457= | Silent (SNP) | VAF 26/92 reads (28%) | called by muse, mutect2, varscan2
- CLEC17A | c.1092C>T p.C364= | Silent (SNP) | VAF 26/157 reads (17%) | called by muse, mutect2, varscan2
- FAM151A | c.1059T>C p.G353= | Silent (SNP) | VAF 45/156 reads (29%) | called by muse, mutect2, varscan2
- MACO1 | c.357A>G p.G119= | Silent (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- MAMDC4 | c.345T>G p.V115= | Silent (SNP) | VAF 56/188 reads (30%) | called by muse, mutect2, varscan2
- PCDHGA4 | c.2217C>A p.V739= | Silent (SNP) | VAF 101/255 reads (40%) | called by muse, mutect2, varscan2
- PRDM11 | c.645C>T p.A215= (on ENST00000530656 / NM_001359633.1; = p.A181= on NM_001256695.1) | Silent (SNP) | VAF 39/160 reads (24%) | called by muse, mutect2, varscan2
- PURB | c.423C>A p.G141= | Silent (SNP) | VAF 64/280 reads (23%) | called by muse, mutect2, varscan2
- SCN8A | c.5457C>A p.L1819= | Silent (SNP) | VAF 33/125 reads (26%) | catalogued as rs1386438615, COSV61977348; called by muse, mutect2, varscan2
- SIDT2 | c.1776G>A p.L592= | Silent (SNP) | VAF 10/280 reads (4%) | called by muse, mutect2
- SLC17A1 | c.975C>T p.F325= | Silent (SNP) | VAF 31/132 reads (23%) | called by muse, mutect2, varscan2
- SNX18 | c.408G>A p.S136= | Silent (SNP) | VAF 58/215 reads (27%) | called by muse, mutect2, varscan2
- UBR4 | c.11637C>A p.V3879= | Silent (SNP) | VAF 47/223 reads (21%) | catalogued as COSV64382840; called by muse, mutect2, varscan2
- ZBTB18 | c.1197C>T p.I399= | Silent (SNP) | VAF 35/118 reads (30%) | called by muse, mutect2, varscan2
- CETN2 | c.*4C>T | 3'UTR (SNP) | VAF 12/84 reads (14%) | called by muse, mutect2, varscan2
- CLN5 | c.340-14C>A | Intron (SNP) | VAF 36/181 reads (20%) | called by muse, mutect2, varscan2
- CPA6 | c.838+94T>C | Intron (SNP) | VAF 34/120 reads (28%) | called by muse, mutect2
- FXYD6P3 | n.262G>C | RNA (SNP) | VAF 31/94 reads (33%) | catalogued as rs1314005270; called by muse, mutect2, varscan2
- HSPD1 | c.*4C>A | 3'UTR (SNP) | VAF 69/274 reads (25%) | called by muse, mutect2, varscan2
- MOV10L1 | c.2627+1315C>A | Intron (SNP) | VAF 57/253 reads (23%) | called by muse, mutect2, varscan2
- PCBP2 | c.1061+3345A>G | Intron (SNP) | VAF 46/168 reads (27%) | called by muse, mutect2, varscan2
- PMS2P3 | n.361C>T | RNA (SNP) | VAF 22/78 reads (28%) | called by muse, mutect2, varscan2
- PPFIA2 | c.304-54440C>T | Intron (SNP) | VAF 51/230 reads (22%) | called by muse, mutect2, varscan2
- PPP3CA | chr4:101348670 A>C | 5'Flank (SNP) | VAF 39/230 reads (17%) | called by muse, mutect2, varscan2
- RP1L1 | c.609+866A>G | Intron (SNP) | VAF 55/232 reads (24%) | catalogued as rs1428109333; called by muse, mutect2, varscan2
- SHQ1 | c.144-1857A>T | Intron (SNP) | VAF 66/173 reads (38%) | called by muse, mutect2, varscan2
- SRSF7 | c.573-338T>C | Intron (SNP) | VAF 44/155 reads (28%) | called by muse, mutect2, varscan2
- UMOD | c.-46del | 5'UTR (DEL) | VAF 45/274 reads (16%) | called by mutect2, pindel, varscan2
